Somatic mutation profile of tumor specimen 0DAWAJ from CCDI case PBBKGA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.8 years (1,755 days).
Specimen 0DAWAJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b824ad23-385a-4f7c-959f-b3a5ca803898.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DAWAD (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ce6ae931-f74a-4113-a389-237913e96b2d

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Splice Region 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMC4 | c.2479C>T p.R827C | Missense Mutation (SNP) | VAF 67/329 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.657); catalogued as rs573812800, COSV61007672; called by muse, mutect2, varscan2
- APOBEC4 | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 30/758 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); called by muse, mutect2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 36/1040 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 40/890 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- VPS41 | c.1740T>A p.I580= | Splice Region (SNP) | VAF 24/851 reads (3%) | called by muse, mutect2
- ZNF763 | c.313T>A p.S105T (on ENST00000358987 / NM_001367172.2; = p.S108T on NM_001012753.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 158/517 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- PPP2R2A | c.973-96A>G | Intron (SNP) | VAF 4/44 reads (9%) | called by mutect2, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 28/176 reads (16%) | called by muse, varscan2
